Surgical pathology report (de-identified scan), TCGA case TCGA-LK-A4O6, project TCGA-MESO (Mesothelioma), tissue source site University of Pittsburgh, specimen TCGA-LK-A4O6-01A (Primary Tumor).

FINAL DIAGNOSIS:

Summary Statement

This extrapleural pneumonectomy specimen shows a biphasic mesothelioma diffusely involving the visceral and parietal pleura. The histology is predominantly epithelioid, with a minor spindle cell component. The tumor invades the diaphragm (non-transmural) and pericardial fat. Isolated tumor nodules within the lung parenchyma, together with the angiolymphatic invasion seen in the lung, are best interpreted as metastatic disease. Almost all submitted lymph nodes are involved by tumor. Pertinent negatives include the absence of pleural plaques, ferruginous/asbestos bodies. [pT3N1M1 AJCC 7th Ed.]

PART 1: LUNG, LEFT LOWER LOBE, WEDGE RESECTION -
MESOTHELIOMA, INVOLVING THE VISCERAL PLEURA.

PART 2: PLEURA, PARIETAL, INCISIONAL BIOPSY -
MESOTHELIOMA.

PART 3: LYMPH NODE, LEVEL 10, BIOPSY -
MESOTHELIOMA IN SUBCAPSULAR SINUSES.

PART 4: LYMPH NODE, LEVEL 11, BIOPSY -
MESOTHELIOMA.

PART 5: LYMPH NODE, NEAR INFERIOR PULMONARY VEIN, BIOPSY -
MESOTHELIOMA.

PART 6: PERICARDIAL FAT, BIOPSY -
MESOTHELIOMA, FORMING MULTIPLE SMALL FOCI IN ADIPOSE TISSUE.

PART 7: DIAPHRAGM FAT, BIOPSY -
MESOTHELIOMA, FORMING ONE SMALL (0.1 CM) IMPLANT IN ADIPOSE TISSUE.

PART 8: LUNG, LEFT, EXTRAPLEURAL PNEUMONECTOMY -
A. BIPHASIC MESOTHELIOMA, PREDOMINANTLY EPITHELIOID WITH MINOR SPINDLE CELL COMPONENT, CIRCUMFERENTIALLY AND DIFFUSELY INVOLVING THE VISCERAL AND PARIETAL PLEURA.
a. SURGICAL MARGINS ARE POSITIVE FOR TUMOR AT THE LATERAL PARIETAL AND INFERIOR PARIETAL PLEURAL MARGINS.
b. BRONCHOVASCULAR MARGINS ARE NEGATIVE FOR TUMOR.
c. ANGIOLYMPHATIC INVASION IS PRESENT.
d. PATHOLOGIC STAGE: pT3N1M1 (AJCC 7th Ed.).
B. METASTATIC MESOTHELIOMA FORMING ISOLATED PULMONARY NODULES.
C. FIVE N1 LYMPH NODES WITH METASTATIC MESOTHELIOMA (5/6).
D. NO FERRUGINOUS/ASBESTOS BODIES IDENTIFIED ON IRON STAINS OF TWO SECTIONS.
E. NO PLEURAL PLAQUE IDENTIFIED.
F. NON-NEOPLASTIC LUNG SHOWING BRONCHIECTASIS AND BRONCHIOLECTASIS WITHOUT INTERSTITIAL FIBROSIS.

PART 9: DIAPHRAGM, RESECTION -
MESOTHELIOMA, INFILTRATING SKELETAL MUSCLE (NON-TRANSMURAL).

COMMENT:
Immunohistochemical staining shows tumor cells to be positive for AE1/2, Cam5.2 and focally positive for calretinin, CK5/6, WT1, D2-40, BerEp4 and CD15. Tumor cells are negative for TAG72, MOC31, monoclonal CEA, PAX-8, inhibin, and TTF-1. Mucin stains (mucicarmine, PASD) are negative. Immunoreactivity for BerEp4 and CD15 is less extensive than that for the other mesothelial markers. The mesothelial markers highlight predominantly the epithelioid component, while the spindle cell component mostly stains with cytokeratin antibodies. A pancytokeratin also stain highlights the tumor cells in the level 10 lymph node (Part 3).

CASE SYNOPSIS:

SYNOPTIC DATA PRIMARY MESOTHELIOMA

SPECIMEN: PLEURA
PROCEDURE: EXTRAPLEURAL PNEUMONECTOMY
SPECIMEN INTEGRITY: DISRUPTED
SPECIMEN LATERALITY: LEFT
TUMOR SITE: PARIETAL PLEURA, VISCERAL PLEURA, DIAPHRAGM, PERICARDIUM
OTHER: LUNG

TUMOR FOCALITY: DIFFUSE
HISTOLOGIC TYPE: BIPHASIC MESOTHELIOMA
TUMOR EXTENSION: CONFLUENT VISCERAL PLEURAL TUMOR (INCLUDING FISSURE), INTO BUT NOT THROUGH DIAPHRAGM, LUNG PARENCHYMA, DIFFUSE OR MULTIPLE FOCI INVADING SOFT TISSUE OF CHEST WALL, INTO BUT NOT THROUGH PERICARDIUM

MARGINS: Margin(s) involved by mesothelioma
Margin(s): Outer soft tissue margin, multifocal
Not applicable

TREATMENT EFFECT:
PATHOLOGIC STAGING (pTNM)

pT3
pN1

Number examined: 9
Number involved: 8

pM1
Site(s): Lung

ADDITIONAL PATHOLOGIC FINDINGS: None identified
ANCILLARY STUDIES: Immunohistochemical stain(s)
Histochemical stain(s)

ICD-O-3
mesothelioma, biphasic, nos 9053/3
Site: pleura, nos C38.4

hw
9/25/12

Source: NCI Genomic Data Commons file 83a341bf-b7a5-4c58-b180-997f7bd85cd9 (TCGA-LK-A4O6.5A8CDA1B-CD49-4177-9716-FD42DE663E29.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).